Gene-level copy-number profile of tumor specimen MP2PRT-PAUILL-TMP1-A from MP2PRT case MP2PRT-PAUILL, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.4 years (2,347 days).
Specimen MP2PRT-PAUILL-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 39d8e333-aab5-4f15-bca0-9eb6c4f5227d.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator MP2PRT-PAUILL-NB1-A (blood derived cancer - peripheral blood, post-treatment); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,719 have no estimate.
https://portal.gdc.cancer.gov/files/948322a7-a96c-4e51-a6be-9429e101ce48

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 111; copy number 1: 3,068; copy number 2: 55,720; copy number 3: 5.

Homozygous deletions (total copy number 0; autosomes only): 111 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:89,128,724–89,192,752, 8 genes (within-gene range 0–2): IGKV2-18, IGKV2-19, IGKV3-20, IGKV6-21, IGKV1-22, IGKV2-23, IGKV2-24, IGKV3-25.
- chr2:89,244,781–89,252,736, 2 genes (within-gene range 0–2): IGKV2-30, IGKV3-31.
- chr2:89,968,867–90,005,629, 4 genes: IGKV1D-27, IGKV2D-26, IGKV3D-25, IGKV2D-24.
- chr14:105,851,705–106,269,140, 80 genes (within-gene range 0–2) (broad region; genes not listed).
- chr14:106,578,744–106,579,236, 1 gene (within-gene range 0–1): IGHV5-51.
- chr14:106,584,718–106,586,826, 2 genes (within-gene range 0–1): IGHVII-51-2, IGHV3-52.
- chr14:106,692,657–106,775,618, 8 genes: IGHVIII-67-3, IGHVIII-67-4, IGHV1-68, IGHV1-69, IGHV2-70D, IGHV1-69D, IGHV2-70, IGHV3-71.
- chr22:22,886,267–22,886,379, 1 gene (within-gene range 0–1): MIR5571.
- chr22:22,893,692–22,905,025, 5 genes (within-gene range 0–1): IGLJ1, IGLC1, IGLJ2, IGLC2, IGLJ3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 212. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
